Somatic mutation profile of tumor specimen MBCProject_0076_T1_WES (aliquot MBCProject_0076_T1_WES_1) from CMI case MBCProject_0076, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 39.1 years (14,292 days).
Specimen MBCProject_0076_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74245357-ad13-41fa-a196-4de4f97dc7c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0076_SALIVA (Saliva), aliquot MBCProject_0076_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e184e19f-1732-4dff-80c2-d5f792f4c03a

The open-access MAF lists 934 somatic variants for this specimen: 639 protein-altering or splice-affecting, 183 silent, 112 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 557, Silent 183, Intron 59, Nonsense Mutation 57, 5'UTR 19, 3'UTR 15, RNA 11, Splice Region 10, Splice Site 8, 5'Flank 6, Frame Shift Del 2, Nonstop Mutation 2.

Variants (750 of 934; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CASR | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs121909259, CM930078, COSV56137950, COSV99072547; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LMNA | c.1318G>A p.V440M | Missense Mutation (SNP) | VAF 183/1080 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs121912493, CM005398; ClinVar: uncertain significance / pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 105/338 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519929, CM126687, COSV55873676, COSV55913749; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 136/178 reads (76%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- WDR35 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 45/166 reads (27%) | catalogued as rs199840434, COSV55606819; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACBD6 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 74/599 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145178556; called by muse, mutect2, varscan2
- ACOT1 | c.434G>C p.R145P | Missense Mutation (SNP) | VAF 63/250 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV58574604; called by muse, mutect2, varscan2
- ACOT2 | c.769G>C p.D257H | Missense Mutation (SNP) | VAF 218/809 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53150249; called by muse, mutect2, varscan2
- ACSS2 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 67/344 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs763781277, COSV53624046; called by muse, mutect2, varscan2
- ACTBL2 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.969); catalogued as rs1313228487, COSV70660968; called by muse, mutect2, varscan2
- ADAMTS18 | c.1266C>G p.I422M | Missense Mutation (SNP) | VAF 103/243 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs372959812; called by muse, mutect2, varscan2
- ADAMTS2 | c.2542G>A p.V848I | Missense Mutation (SNP) | VAF 81/350 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.122); catalogued as rs766088822; called by muse, mutect2, varscan2
- ADCY10 | c.679G>C p.D227H | Missense Mutation (SNP) | VAF 66/437 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100897027; called by muse, mutect2, varscan2
- ADGRB2 | c.434C>G p.S145* | Nonsense Mutation (SNP) | VAF 144/321 reads (45%) | catalogued as COSV57078804; called by muse, mutect2, varscan2
- ADGRF3 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs866574269; called by muse, varscan2
- AKAP11 | c.4274G>C p.R1425T | Missense Mutation (SNP) | VAF 24/297 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as rs1373288232; called by muse, mutect2
- ALDOB | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 138/513 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV66398111, COSV66398756; called by muse, mutect2, varscan2
- AMBRA1 | c.3210-1G>C p.X1070_splice (on ENST00000458649 / NM_001367468.1; = p.X980_splice on NM_017749.3 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 12/37 reads (32%) | catalogued as COSV100094050; called by muse, mutect2
- AMER1 | c.3146G>C p.R1049P | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as COSV57665246; called by muse, mutect2, varscan2
- ANGPTL2 | c.729G>C p.Q243H | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV99402060; called by muse, mutect2, varscan2
- ANK3 | c.3112G>A p.E1038K (on ENST00000280772 / NM_001320874.2; = p.E172K on NM_001149.3) | Missense Mutation (SNP) | VAF 96/521 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55046407; called by muse, mutect2, varscan2
- ANKRD36C | c.1532-1G>A p.X511_splice | Splice Site (SNP) | VAF 20/165 reads (12%) | catalogued as rs1185667369; called by muse, varscan2
- ANKRD62 | c.1741C>T p.Q581* | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | catalogued as COSV58410754; called by muse, mutect2, varscan2
- APEH | c.1788G>C p.L596F | Missense Mutation (SNP) | VAF 35/404 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56532806; called by muse, mutect2
- APLF | c.1381G>C p.E461Q | Missense Mutation (SNP) | VAF 85/391 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs1221229078, COSV58145348, COSV58147149; called by muse, mutect2, varscan2
- ARHGAP12 | c.1666C>T p.Q556* | Nonsense Mutation (SNP) | VAF 94/474 reads (20%) | catalogued as COSV60961774; called by muse, varscan2
- ARHGAP20 | c.1462C>G p.L488V | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.753); catalogued as rs1021217377, COSV99505659; called by muse, varscan2
- ARHGEF28 | c.911-3C>T | Splice Region (SNP) | VAF 24/350 reads (7%) | catalogued as rs755340442; called by muse, mutect2
- ARHGEF40 | c.3064G>C p.E1022Q | Missense Mutation (SNP) | VAF 132/722 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.199); catalogued as COSV100069934; called by muse, mutect2, varscan2
- ARMC10 | c.185C>T p.S62L | Missense Mutation (SNP) | VAF 45/240 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs149036313, COSV57540616; called by muse, mutect2, varscan2
- ARMC4 | c.572C>G p.S191* | Nonsense Mutation (SNP) | VAF 29/214 reads (14%) | catalogued as COSV53465549; called by muse, mutect2, varscan2
- ATP1B2 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 121/373 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.155); catalogued as COSV100006921; called by muse, mutect2, varscan2
- ATXN2L | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs776614927, COSV57366960; called by muse, mutect2, varscan2
- AXIN1 | c.2530G>A p.E844K | Missense Mutation (SNP) | VAF 132/615 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as rs769195055; called by muse, mutect2, varscan2
- AXIN1 | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 126/612 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99250109; called by muse, mutect2, varscan2
- BCR | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV59929310; called by muse, mutect2, varscan2
- BRAP | c.82+3G>A | Splice Region (SNP) | VAF 35/175 reads (20%) | catalogued as COSV100554134, COSV100554316, COSV58155242; called by muse, mutect2, varscan2
- BTAF1 | c.5467C>G p.L1823V | Missense Mutation (SNP) | VAF 73/319 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV56432523; called by muse, mutect2, varscan2
- C1RL | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 53/197 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.234); catalogued as rs369851400, COSV99864692; called by muse, mutect2, varscan2
- C5orf22 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 87/348 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as COSV57597323; called by muse, mutect2, varscan2
- C9 | c.832G>C p.E278Q | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.711); catalogued as COSV54678843; called by muse, mutect2, varscan2
- CALCRL | c.548C>G p.S183* | Nonsense Mutation (SNP) | VAF 40/213 reads (19%) | catalogued as COSV66477458; called by muse, mutect2, varscan2
- CAMK1G | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 51/445 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs375301374; called by muse, mutect2, varscan2
- CAPN7 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 63/250 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.627); catalogued as rs1239915438; called by muse, mutect2, varscan2
- CCDC168 | c.18094C>T p.R6032C | Missense Mutation (SNP) | VAF 56/199 reads (28%) | SIFT tolerated (0.95); PolyPhen benign (0.005); catalogued as rs1454294230; called by muse, mutect2, varscan2
- CCDC185 | c.1687G>C p.E563Q | Missense Mutation (SNP) | VAF 37/263 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV64820707; called by muse, mutect2, varscan2
- CCDC27 | c.319-1G>C p.X107_splice | Splice Site (SNP) | VAF 33/82 reads (40%) | catalogued as COSV99622451; called by muse, mutect2, varscan2
- CCDC39 | c.2551G>A p.E851K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as CM110033; called by muse, mutect2
- CCND3 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 42/1472 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0.129); catalogued as COSV65913381; called by muse, mutect2
- CCSER2 | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 20/323 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.585); catalogued as COSV56511563; called by muse, mutect2
- CDC42BPA | c.2174C>T p.S725L | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV62024537; called by muse, mutect2, varscan2
- CEACAM21 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.962); catalogued as rs782767735; called by muse, mutect2, varscan2
- CELSR3 | c.4454G>A p.R1485H | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV50839517; called by muse, mutect2, varscan2
- CEP250 | c.2770G>C p.E924Q | Missense Mutation (SNP) | VAF 35/229 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.892); catalogued as COSV61171815; called by muse, mutect2, varscan2
- CEP350 | c.6097G>A p.D2033N | Missense Mutation (SNP) | VAF 62/1052 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as rs1159462447; called by muse, mutect2
- CHD4 | c.2831G>A p.R944Q (on ENST00000357008 / NM_001363606.2; = p.R957Q on NM_001273.5) | Missense Mutation (SNP) | VAF 110/199 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs76359472, COSV104399234, COSV58904513; called by muse, mutect2, varscan2
- CLEC17A | c.242C>G p.S81* | Nonsense Mutation (SNP) | VAF 27/160 reads (17%) | catalogued as COSV100355552; called by muse, mutect2, varscan2
- CNKSR2 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 60/264 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.261); catalogued as COSV54265374; called by muse, mutect2, varscan2
- CNNM3 | c.1901C>G p.S634C | Missense Mutation (SNP) | VAF 41/484 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as rs781153668; called by muse, mutect2
- COG5 | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 78/372 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99773622; called by muse, mutect2, varscan2
- COL4A5 | c.3811C>T p.P1271S | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.686); catalogued as rs761470284; called by muse, varscan2
- COL5A3 | c.1683G>C p.E561D | Missense Mutation (SNP) | VAF 95/343 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.034); catalogued as COSV53411318, COSV53412750; called by muse, mutect2, varscan2
- COMT | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 175/402 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.407); catalogued as rs984098043; called by muse, mutect2, varscan2
- CPXCR1 | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as COSV99342234; called by muse, mutect2, varscan2
- CTDP1 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 30/782 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1032972561; called by muse, mutect2
- CTNNA3 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.816); catalogued as COSV65629164; called by muse, mutect2, varscan2
- CUBN | c.253-1G>T p.X85_splice | Splice Site (SNP) | VAF 12/86 reads (14%) | catalogued as COSV64701966; called by muse, mutect2, varscan2
- CWF19L1 | c.1106G>C p.G369A | Missense Mutation (SNP) | VAF 104/442 reads (24%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.896); catalogued as COSV100821433, COSV62499512; called by muse, mutect2, varscan2
- CYLD | c.906C>G p.I302M | Missense Mutation (SNP) | VAF 84/765 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as COSV61093564; called by muse, varscan2
- DBF4 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as COSV55998308; called by muse, varscan2
- DCST1 | c.790G>C p.D264H | Missense Mutation (SNP) | VAF 102/753 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.358); catalogued as COSV55063655; called by muse, varscan2
- DDX11 | c.2834G>C p.R945T | Missense Mutation (SNP) | VAF 51/228 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV52509359; called by muse, mutect2, varscan2
- DDX18 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1325956689; called by muse, mutect2, varscan2
- DLGAP1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.036); catalogued as rs372048186; called by muse, mutect2, varscan2
- DNAJC14 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs1565690045, COSV100423681; called by muse, mutect2
- DOCK6 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1202876206; called by muse, mutect2, varscan2
- DOCK7 | c.4501G>C p.E1501Q (on ENST00000635253 / NM_001367561.1; = p.E1470Q on NM_033407.3) | Missense Mutation (SNP) | VAF 95/228 reads (42%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.573); catalogued as COSV99226355; called by muse, mutect2, varscan2
- DST | c.8390C>T p.P2797L | Missense Mutation (SNP) | VAF 69/355 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.308); catalogued as rs772330396; called by muse, mutect2, varscan2
- EBAG9 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as rs1487806178; called by muse, mutect2
- EIF4A2 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 65/1100 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs374075692; called by muse, mutect2
- EIF4G1 | c.3371C>A p.S1124* (on ENST00000346169 / NM_198241.3; = p.S929* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 163/780 reads (21%) | catalogued as COSV59989805; called by muse, mutect2, varscan2
- ELMO1 | c.983G>C p.R328P | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60296526; called by muse, mutect2, varscan2
- ERICH6 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.566); catalogued as rs908459135; called by muse, varscan2
- ERICH6B | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as rs1294923058; called by muse, mutect2, varscan2
- FAM205A | c.363G>C p.E121D | Missense Mutation (SNP) | VAF 47/257 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.945); catalogued as COSV101113029; called by muse, mutect2, varscan2
- FAM78A | c.73C>G p.Q25E | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV100953481; called by muse, mutect2, varscan2
- FBN3 | c.2569C>T p.R857W | Missense Mutation (SNP) | VAF 54/214 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs780755016; called by muse, mutect2, varscan2
- FCRL3 | c.1571C>G p.S524C | Missense Mutation (SNP) | VAF 88/620 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); catalogued as COSV63839128; called by muse, mutect2, varscan2
- FEZF2 | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.014); catalogued as rs1452224683; called by muse, mutect2, varscan2
- FOXN4 | c.1249G>T p.E417* | Nonsense Mutation (SNP) | VAF 48/350 reads (14%) | catalogued as COSV54497048; called by muse, mutect2, varscan2
- FREM1 | c.5414C>G p.S1805* | Nonsense Mutation (SNP) | VAF 20/92 reads (22%) | catalogued as rs1421549126; called by muse, mutect2
- FRRS1L | c.697C>G p.P233A | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV73747035; called by muse, mutect2, varscan2
- GABRD | c.844C>G p.L282V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99059625; called by mutect2, varscan2
- GPN2 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); catalogued as COSV64652339; called by muse, mutect2
- GPR18 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs149113944; called by muse, mutect2, varscan2
- GRP | c.5G>A p.R2H | Missense Mutation (SNP) | VAF 76/81 reads (94%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.848); catalogued as rs760680754; called by muse, mutect2, varscan2
- GTF2B | c.654C>G p.F218L | Missense Mutation (SNP) | VAF 64/184 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV65137657; called by muse, mutect2, varscan2
- H1-2 | c.97C>G p.R33G | Missense Mutation (SNP) | VAF 120/694 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs766992808, COSV59190773; called by muse, mutect2, varscan2
- HADHA | c.391del p.E131Kfs*30 | Frame Shift Del (DEL) | VAF 72/540 reads (13%) | catalogued as COSV66106318; called by pindel, varscan2
- HOMER3 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.105); catalogued as rs149686899; called by muse, mutect2, varscan2
- HSPH1 | c.2471A>C p.K824T | Missense Mutation (SNP) | VAF 87/298 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV60712209; called by muse, mutect2, varscan2
- HYAL4 | c.858G>C p.M286I | Missense Mutation (SNP) | VAF 67/407 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV56139530; called by muse, mutect2, varscan2
- IER2 | c.208C>A p.R70S | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as rs1008234150, CM142435; called by muse, mutect2, varscan2
- INAFM1 | c.34G>C p.E12Q | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as rs954626001; called by muse, mutect2, varscan2
- ING1 | c.112C>G p.L38V | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.118); catalogued as rs1017905727; called by muse, mutect2, varscan2
- INTS5 | c.1825G>C p.D609H | Missense Mutation (SNP) | VAF 68/273 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs1383273552, COSV57953001; called by muse, mutect2, varscan2
- ITPR2 | c.6553G>A p.E2185K | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101190161; called by muse, mutect2, varscan2
- KCNK2 | c.137C>T p.S46F (on ENST00000444842 / NM_001017425.3; = p.S31F on NM_014217.4) | Missense Mutation (SNP) | VAF 75/599 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV67202875; called by muse, mutect2, varscan2
- KDM3B | c.1006G>C p.D336H | Missense Mutation (SNP) | VAF 19/410 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV58687382; called by muse, mutect2
- KIF5C | c.2435G>A p.R812Q | Missense Mutation (SNP) | VAF 61/478 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as rs770338912; called by muse, mutect2, varscan2
- KNG1 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 68/420 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.199); catalogued as rs878922781; called by muse, varscan2
- L3HYPDH | c.383C>T p.T128I | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs778118489; called by muse, mutect2, varscan2
- LAMP3 | c.772C>G p.R258G | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as COSV55614133; called by muse, mutect2, varscan2
- LCMT2 | c.244C>A p.R82S | Missense Mutation (SNP) | VAF 73/178 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.075); catalogued as COSV59789944, COSV59791207; called by muse, varscan2
- LGALS9B | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 31/308 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs376428526; called by muse, mutect2
- LGSN | c.932C>G p.S311* | Nonsense Mutation (SNP) | VAF 36/144 reads (25%) | catalogued as COSV65727725; called by muse, mutect2, varscan2
- LIN37 | c.146C>G p.S49* | Nonsense Mutation (SNP) | VAF 94/462 reads (20%) | catalogued as COSV99137374; called by muse, mutect2, varscan2
- LINGO3 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs1295059264; called by muse, mutect2, varscan2
- LMOD1 | c.717G>A p.M239I | Missense Mutation (SNP) | VAF 75/698 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1472149440; called by muse, mutect2, varscan2
- LOX | c.419C>G p.S140W | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.366); catalogued as COSV50241067; called by muse, mutect2, varscan2
- LPCAT3 | c.1331G>C p.W444S | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV99780955; called by muse, mutect2, varscan2
- LRIF1 | c.62C>G p.S21W | Missense Mutation (SNP) | VAF 69/375 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs752314346, COSV63896890, COSV63897061; called by muse, mutect2, varscan2
- LRP6 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 79/347 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV53783184; called by muse, mutect2, varscan2
- LRRC14B | c.1482C>G p.F494L | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV99722948; called by muse, mutect2
- MAGED1 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 57/491 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as rs782818810, COSV58515197; called by muse, mutect2, varscan2
- MAML1 | c.381G>T p.Q127H | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.695); catalogued as rs1412183480; called by muse, mutect2
- MAPK15 | c.1021C>G p.Q341E | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1159344009, COSV100567906; called by muse, mutect2
- MAPK8IP3 | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 23/438 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV51725141; called by muse, mutect2
- MARF1 | c.4008C>G p.F1336L | Missense Mutation (SNP) | VAF 18/522 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs1340364063; called by muse, mutect2
- MARK2 | c.1500G>C p.Q500H (on ENST00000402010 / NM_001039469.2; = p.Q499H on NM_004954.5) | Missense Mutation (SNP) | VAF 46/275 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV100158952; called by muse, mutect2, varscan2
- MBD3L3 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 174/1406 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); catalogued as rs749130271; called by muse, mutect2, varscan2
- MEP1A | c.120G>T p.Q40H | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.246); catalogued as rs1422956297; called by muse, mutect2
- MGAT5B | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV56926955; called by muse, mutect2, varscan2
- MGRN1 | c.1589G>A p.R530Q | Missense Mutation (SNP) | VAF 89/451 reads (20%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.048); catalogued as rs762339568, COSV52154923; called by muse, mutect2, varscan2
- MIB2 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 93/272 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.021); catalogued as rs1380907254; called by muse, mutect2, varscan2
- MKLN1 | c.74C>G p.S25C | Missense Mutation (SNP) | VAF 96/508 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100759851; called by muse, mutect2, varscan2
- MON1B | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 87/172 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778369868; called by muse, mutect2, varscan2
- MPIG6B | c.725G>C p.*242Sext*11 | Nonstop Mutation (SNP) | VAF 62/244 reads (25%) | catalogued as COSV101008104; called by muse, mutect2, varscan2
- MPZ | c.352G>C p.D118H | Missense Mutation (SNP) | VAF 39/680 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as CM042088; called by muse, mutect2
- MROH6 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 96/324 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.219); catalogued as rs199706043; called by muse, varscan2
- MRPL38 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 38/258 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.534); catalogued as rs750505903; called by muse, varscan2
- MTR | c.1532C>A p.T511K | Missense Mutation (SNP) | VAF 104/764 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs766183529; called by muse, mutect2, varscan2
- MTTP | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 88/199 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.755); catalogued as COSV55504728; called by muse, mutect2, varscan2
- MUC1 | c.2924C>T p.S975L (on ENST00000611571 / NM_001371720.1; = p.S188L on NM_001204285.2) | Missense Mutation (SNP) | VAF 33/310 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1319016202; called by muse, mutect2, varscan2
- NBEAL2 | c.3028G>C p.E1010Q | Missense Mutation (SNP) | VAF 99/306 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV99434407; called by muse, mutect2, varscan2
- NBPF20 | c.16650_16652del p.R5551del (on ENST00000369373; = p.R5112del on NM_001278267.1) | In Frame Del (DEL) | VAF 116/672 reads (17%) | catalogued as rs782474370; called by pindel, varscan2
- NCLN | c.509C>G p.S170C | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV55743282; called by muse, mutect2, varscan2
- NDC80 | c.1010G>C p.R337T | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV55247855; called by muse, mutect2
- NELFA | c.628G>A p.A210T (on ENST00000542778; = p.A199T on NM_005663.5) | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs201479105; called by muse, mutect2, varscan2
- NEMF | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 71/470 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53592524; called by muse, mutect2, varscan2
- NFATC4 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 45/575 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.416); catalogued as rs1277887603; called by muse, mutect2
- NFKBIE | c.769G>C p.E257Q (on ENST00000275015; = p.E118Q on NM_004556.3) | Missense Mutation (SNP) | VAF 161/1102 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1293946984, COSV51492406; called by muse, mutect2, varscan2
- NIBAN1 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 44/312 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369740091; called by muse, mutect2, varscan2
- NIN | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 113/570 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55382999; called by muse, varscan2
- NKX2-8 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 70/265 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs753841581, COSV51874244, COSV99352366; called by muse, mutect2, varscan2
- NME8 | c.1397G>C p.R466T | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV52254981; called by muse, mutect2, varscan2
- NOBOX | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.015); catalogued as rs867952672, COSV56197673; called by muse, mutect2, varscan2
- NPHP3 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 57/278 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV58631419; called by muse, mutect2, varscan2
- NPHP3 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 80/429 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.118); catalogued as rs1402433942; called by muse, mutect2, varscan2
- NPM1 | c.7G>C p.D3H | Missense Mutation (SNP) | VAF 87/527 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV51561387; called by muse, mutect2, varscan2
- NRXN2 | c.2117G>A p.R706Q | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.388); catalogued as rs1246836172, COSV55450790, COSV55461280; called by muse, mutect2, varscan2
- OR2B11 | c.352G>A p.V118I | Missense Mutation (SNP) | VAF 39/306 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs763009869, COSV59511357; called by muse, mutect2, varscan2
- OSR1 | c.785C>G p.S262C | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.321); catalogued as COSV55344698; called by muse, mutect2
- OTOA | c.855C>G p.I285M | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53750216; called by muse, mutect2, varscan2
- OXGR1 | c.271C>A p.H91N | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53658138; called by muse, mutect2, varscan2
- PABPC3 | c.1380G>C p.M460I | Missense Mutation (SNP) | VAF 58/280 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs759451460; called by muse, varscan2
- PACSIN3 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 54/305 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV54065224; called by muse, mutect2, varscan2
- PAXBP1 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 114/509 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.164); catalogued as rs1179013014; called by muse, mutect2, varscan2
- PCDHB1 | c.2208C>G p.F736L | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.628); catalogued as COSV100128045; called by muse, mutect2, varscan2
- PEX1 | c.2080G>T p.D694Y | Missense Mutation (SNP) | VAF 50/319 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV50394680, COSV50405282; called by muse, mutect2, varscan2
- PGM3 | c.1196G>C p.R399T | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as COSV99392105; called by muse, mutect2, varscan2
- PHACTR3 | c.671C>A p.S224Y | Missense Mutation (SNP) | VAF 85/465 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV63033933; called by muse, mutect2, varscan2
- PHLDB1 | c.2237G>A p.R746Q | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0.044); catalogued as rs369630236; called by muse, varscan2
- PHOSPHO2 | c.471G>C p.L157F | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs115118429; called by muse, varscan2
- PIAS3 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 62/454 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as rs1018079308; called by muse, mutect2, varscan2
- PIEZO1 | c.6915G>C p.W2305C | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754305193; called by muse, mutect2, varscan2
- PIGB | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 56/111 reads (50%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1285271538; called by muse, mutect2, varscan2
- PIK3C2G | c.64C>G p.Q22E | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.085); catalogued as COSV56813410; called by muse, varscan2
- PLXDC2 | c.1487G>A p.R496K | Missense Mutation (SNP) | VAF 47/433 reads (11%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.876); catalogued as rs143829207; called by muse, mutect2, varscan2
- POPDC3 | c.280C>T p.H94Y | Missense Mutation (SNP) | VAF 108/259 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV99633554; called by muse, mutect2, varscan2
- PPFIA4 | c.1342G>A p.E448K (on ENST00000447715; = p.E444K on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/544 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV99690507; called by muse, mutect2
- PPP4R3B | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 68/271 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55403149; called by muse, mutect2, varscan2
- PRDM15 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 156/624 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs749501331; called by muse, mutect2, varscan2
- PRMT6 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 21/565 reads (4%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.031); catalogued as COSV63655403; called by muse, mutect2
- PROKR2 | c.756C>G p.F252L | Missense Mutation (SNP) | VAF 79/361 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54089895; called by muse, mutect2, varscan2
- PRRX1 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs1453716808, COSV53415587; called by muse, mutect2, varscan2
- PRTG | c.3352G>C p.E1118Q | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.941); catalogued as COSV66836899; called by muse, mutect2, varscan2
- PTCHD4 | c.1916G>A p.R639Q | Missense Mutation (SNP) | VAF 45/236 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.069); catalogued as rs912676727, COSV59796694; called by muse, mutect2, varscan2
- PTPRO | c.265C>G p.H89D | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV55507494; called by muse, mutect2, varscan2
- QARS1 | c.1984G>T p.E662* | Nonsense Mutation (SNP) | VAF 22/304 reads (7%) | catalogued as COSV60273753; called by muse, mutect2
- RALGAPB | c.1270C>T p.Q424* | Nonsense Mutation (SNP) | VAF 91/594 reads (15%) | catalogued as COSV53439406; called by muse, mutect2, varscan2
- RFX5 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 102/681 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as COSV51839844, COSV51840184; called by muse, mutect2, varscan2
- RNASE9 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV58880314; called by muse, mutect2
- RNF168 | c.1423C>G p.H475D | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100534949, COSV58838058; called by muse, mutect2, varscan2
- RNF185 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs201108552; called by muse, mutect2, varscan2
- RNF19A | c.29C>G p.S10C | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.037); catalogued as COSV61993609; called by muse, mutect2
- RTN2 | c.1239C>T p.F413= | Splice Region (SNP) | VAF 68/246 reads (28%) | catalogued as rs917119159; called by muse, varscan2
- RYR1 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 104/343 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199826952, COSV62109089; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SALL3 | c.3083G>C p.R1028T | Missense Mutation (SNP) | VAF 142/895 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs573157685, COSV73306096; called by muse, mutect2, varscan2
- SCUBE3 | c.2644G>A p.E882K | Missense Mutation (SNP) | VAF 118/366 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767056176; called by muse, mutect2, varscan2
- SEMA6C | c.1834G>A p.A612T | Missense Mutation (SNP) | VAF 65/443 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as rs757769530; called by muse, mutect2, varscan2
- SEMG2 | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.995); catalogued as COSV65647850; called by muse, mutect2, varscan2
- SETD5 | c.1715C>T p.S572L | Missense Mutation (SNP) | VAF 126/343 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs751539788, COSV56711158; called by muse, mutect2, varscan2
- SH3KBP1 | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as rs373849479, COSV65647910; called by muse, mutect2, varscan2
- SHB | c.191C>G p.S64* | Nonsense Mutation (SNP) | VAF 94/353 reads (27%) | catalogued as COSV66621088; called by muse, mutect2, varscan2
- SLC22A24 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 78/328 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); catalogued as rs753139006, COSV58222250; called by muse, mutect2, varscan2
- SLC22A9 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 16/90 reads (18%) | catalogued as rs915745586; called by muse, varscan2
- SLC26A4 | c.958G>C p.E320Q | Missense Mutation (SNP) | VAF 33/495 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.223); catalogued as COSV55918880; called by muse, mutect2
- SLC27A4 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 57/473 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs756888086; called by muse, mutect2, varscan2
- SLC5A12 | c.409C>T p.L137F | Missense Mutation (SNP) | VAF 59/321 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54819194; called by muse, mutect2, varscan2
- SLCO4C1 | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV60512305; called by muse, mutect2
- SLU7 | c.1051G>C p.E351Q | Missense Mutation (SNP) | VAF 30/348 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.896); catalogued as COSV51786879; called by muse, mutect2
- SOS2 | c.2466G>A p.M822I | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.247); catalogued as rs1272374280; called by muse, mutect2, varscan2
- SOWAHB | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as rs891333401; called by muse, mutect2
- SOX12 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 195/1044 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1157480305; called by muse, mutect2, varscan2
- SP140L | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.208); catalogued as COSV54748660; called by muse, mutect2, varscan2
- SPATA31A6 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 95/347 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.227); catalogued as COSV60535738; called by muse, mutect2, varscan2
- SPINK5 | c.1876G>C p.E626Q | Missense Mutation (SNP) | VAF 118/555 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.911); catalogued as COSV99807594; called by muse, mutect2, varscan2
- TADA3 | c.1272G>C p.E424D | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs1245567569, COSV100113113; called by muse, mutect2, varscan2
- TAS2R50 | c.871C>G p.L291V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); catalogued as COSV101114716, COSV67858437; called by muse, mutect2, varscan2
- TBC1D2B | c.2714C>G p.S905C | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV56039485; called by muse, mutect2, varscan2
- TBL3 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 124/718 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs373997979; called by muse, mutect2, varscan2
- TG | c.6666G>A p.W2222* | Nonsense Mutation (SNP) | VAF 122/805 reads (15%) | catalogued as COSV55092199; called by muse, mutect2, varscan2
- THAP7 | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs1273033870; called by muse, mutect2, varscan2
- THNSL1 | c.163G>C p.D55H | Missense Mutation (SNP) | VAF 84/401 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.688); catalogued as COSV64479000; called by muse, mutect2, varscan2
- THOC2 | c.1191-1G>C p.X397_splice | Splice Site (SNP) | VAF 17/61 reads (28%) | catalogued as COSV99834083; called by muse, mutect2, varscan2
- TK2 | c.282-8C>G | Splice Region (SNP) | VAF 289/542 reads (53%) | catalogued as rs1240258827; called by muse, mutect2, varscan2
- TLN2 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs532505276, COSV60893303; called by muse, mutect2, varscan2
- TMED1 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 17/232 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs777431667; called by muse, mutect2
- TMEM132D | c.2874G>A p.M958I | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs753644162, COSV99066504; called by muse, mutect2, varscan2
- TMEM62 | c.98C>G p.S33W | Missense Mutation (SNP) | VAF 80/207 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as rs1011242926; called by muse, mutect2, varscan2
- TMPO | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 187/787 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.313); catalogued as rs1285853015; called by muse, mutect2, varscan2
- TNRC18 | c.487+5G>C | Splice Region (SNP) | VAF 58/291 reads (20%) | catalogued as rs1220086693; called by muse, mutect2, varscan2
- TPH2 | c.562C>T p.R188* | Nonsense Mutation (SNP) | VAF 72/237 reads (30%) | catalogued as COSV61595016; called by muse, mutect2, varscan2
- TPRN | c.989C>G p.S330C | Missense Mutation (SNP) | VAF 92/709 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757165154, COSV58809159; called by muse, mutect2, varscan2
- TTC14 | c.404C>A p.S135Y | Missense Mutation (SNP) | VAF 123/716 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV56009329, COSV56013019; called by muse, mutect2, varscan2
- TTC14 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 51/315 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); catalogued as rs777553737; called by muse, mutect2, varscan2
- TTN | c.73766G>A p.G24589E (on ENST00000591111; = p.G17165E on NM_003319.4) | Missense Mutation (SNP) | VAF 25/94 reads (27%) | PolyPhen probably damaging (0.959); catalogued as COSV60282485; called by muse, mutect2, varscan2
- UBTF | c.1906-1G>C p.X636_splice | Splice Site (SNP) | VAF 79/154 reads (51%) | catalogued as COSV99044323; called by muse, mutect2, varscan2
- UCN | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 115/449 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.167); catalogued as rs773388238; called by muse, mutect2, varscan2
- USH2A | c.4046C>G p.S1349C | Missense Mutation (SNP) | VAF 25/280 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.819); catalogued as CD1413402; called by muse, mutect2
- USPL1 | c.1790C>T p.S597L | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.258); catalogued as rs1372689176; called by muse, mutect2, varscan2
- VCAN | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 71/438 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV54110103; called by muse, mutect2, varscan2
- VIT | c.96G>C p.K32N | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV64895591; called by muse, mutect2, varscan2
- VPS13A | c.8872G>A p.E2958K | Missense Mutation (SNP) | VAF 19/426 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1563967454; called by muse, mutect2
- WDR18 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 112/385 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs372604451; called by muse, mutect2, varscan2
- WDR97 | c.4139C>T p.S1380L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs1055417084; called by muse, mutect2, varscan2
- WFIKKN1 | c.1369G>A p.V457M | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs752283984; called by muse, mutect2, varscan2
- ZKSCAN4 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 17/183 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs372060515; called by muse, mutect2
- ZNF273 | c.29C>A p.S10Y | Missense Mutation (SNP) | VAF 77/386 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.034); catalogued as COSV99060349; called by muse, mutect2, varscan2
- ZNF276 | c.1034C>G p.S345C (on ENST00000443381 / NM_001113525.2; = p.S270C on NM_152287.4) | Missense Mutation (SNP) | VAF 95/235 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.936); catalogued as rs374799599; called by muse, varscan2
- ZNF354C | c.1109C>G p.S370C | Missense Mutation (SNP) | VAF 45/195 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV59608727, COSV59609147; called by muse, mutect2, varscan2
- ZNF638 | c.268C>G p.H90D | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV52491618; called by muse, mutect2, varscan2
- ZNF677 | c.1492G>T p.E498* | Nonsense Mutation (SNP) | VAF 56/168 reads (33%) | catalogued as COSV100447853; called by muse, mutect2, varscan2
- ZNF729 | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.697); catalogued as rs1161110163; called by muse, mutect2, varscan2
- ABCA12 | c.5414C>T p.S1805L (on ENST00000272895 / NM_173076.3; = p.S1487L on NM_015657.3) | Missense Mutation (SNP) | VAF 146/518 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- ABHD16B | c.1174G>C p.D392H | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2
- ADAMTS6 | c.364C>T p.Q122* | Nonsense Mutation (SNP) | VAF 45/214 reads (21%) | called by muse, mutect2, varscan2
- ADAMTSL5 | c.220G>T p.D74Y | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADCY6 | c.2112C>G p.I704M | Missense Mutation (SNP) | VAF 18/364 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.221); called by muse, mutect2
- ADGRA3 | c.3161G>C p.R1054T | Missense Mutation (SNP) | VAF 106/198 reads (54%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- ADSS2 | c.977G>C p.R326T | Missense Mutation (SNP) | VAF 54/436 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- AFAP1L1 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 117/584 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- AFDN | c.1461G>A p.M487I | Missense Mutation (SNP) | VAF 22/408 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.039); called by muse, mutect2
- AGBL2 | c.2339C>A p.S780* | Nonsense Mutation (SNP) | VAF 26/108 reads (24%) | called by muse, varscan2
- AHCYL2 | c.650G>C p.R217T | Missense Mutation (SNP) | VAF 66/333 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- AL136295.1 | c.1655C>T p.S552L | Missense Mutation (SNP) | VAF 132/608 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- ALMS1 | c.5426G>C p.R1809T | Missense Mutation (SNP) | VAF 102/331 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ALPK2 | c.1493T>A p.L498H | Missense Mutation (SNP) | VAF 82/201 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMY1B | c.917G>C p.R306T | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.267); called by mutect2, varscan2
- ANK3 | c.6752G>C p.R2251T | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ANKRD62 | c.2128G>C p.E710Q | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ANKRD62 | c.2468G>C p.R823T | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- ANPEP | c.143C>G p.S48C | Missense Mutation (SNP) | VAF 25/529 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.237); called by muse, mutect2
- AP5Z1 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); called by muse, varscan2
- ARMH4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ASIC2 | c.928G>T p.D310Y | Missense Mutation (SNP) | VAF 60/341 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ASL | c.821C>G p.S274* | Nonsense Mutation (SNP) | VAF 148/675 reads (22%) | called by muse, mutect2, varscan2
- ATAD5 | c.3029G>C p.R1010T | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ATP10D | c.4006G>C p.D1336H | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ATP11B | c.2911C>T p.H971Y | Missense Mutation (SNP) | VAF 45/372 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- ATP13A3 | c.3247C>T p.Q1083* | Nonsense Mutation (SNP) | VAF 92/511 reads (18%) | called by muse, mutect2, varscan2
- ATP13A3 | c.2296C>G p.L766V | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.034); called by muse, varscan2
- ATP6V1C1 | c.115A>C p.N39H | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ATR | c.7653G>C p.M2551I | Missense Mutation (SNP) | VAF 15/317 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.687); called by muse, mutect2
- ATRN | c.2461G>A p.A821T | Missense Mutation (SNP) | VAF 51/328 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- AXIN1 | c.2512G>A p.E838K | Missense Mutation (SNP) | VAF 109/539 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BHMT2 | c.192G>C p.L64F | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- BLM | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- BPIFA1 | c.421G>C p.V141L | Missense Mutation (SNP) | VAF 62/280 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- C11orf49 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 111/563 reads (20%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- C16orf96 | c.611C>G p.S204C | Missense Mutation (SNP) | VAF 41/242 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- C19orf53 | c.75G>C p.K25N | Missense Mutation (SNP) | VAF 119/454 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.093); called by muse, varscan2
- C1orf21 | c.260G>T p.R87I | Missense Mutation (SNP) | VAF 91/619 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- C1orf56 | c.829C>G p.Q277E | Missense Mutation (SNP) | VAF 36/294 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- C4B | c.3475G>A p.E1159K | Missense Mutation (SNP) | VAF 68/617 reads (11%) | SIFT tolerated (0.93); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C8orf76 | c.587C>G p.S196* | Nonsense Mutation (SNP) | VAF 23/281 reads (8%) | called by muse, mutect2
- CABIN1 | c.4930G>A p.D1644N | Missense Mutation (SNP) | VAF 169/421 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CACNA1C | c.6136G>C p.E2046Q (on ENST00000399634 / NM_001167625.1; = p.E1975Q on NM_000719.7) | Missense Mutation (SNP) | VAF 79/309 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CACNB2 | c.1147C>G p.Q383E (on ENST00000324631 / NM_201596.3; = p.Q328E on NM_000724.4) | Missense Mutation (SNP) | VAF 89/437 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CAMK1G | c.562C>G p.P188A | Missense Mutation (SNP) | VAF 51/423 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAP2 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 175/754 reads (23%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- CASKIN2 | c.335C>T p.S112L | Missense Mutation (SNP) | VAF 103/381 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CASP8 | c.1365C>G p.D455E (on ENST00000432109 / NM_033355.3; = p.D472E on NM_001228.4) | Missense Mutation (SNP) | VAF 116/453 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCDC14 | c.2528C>T p.S843L (on ENST00000488653; = p.S795L on NM_022757.5) | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC178 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- CCDC191 | c.84T>A p.S28R | Missense Mutation (SNP) | VAF 104/352 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- CCDC33 | c.264G>T p.Q88H | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.08); called by muse, mutect2
- CCDC7 | c.721C>G p.L241V | Missense Mutation (SNP) | VAF 31/273 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC70 | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- CCDC93 | c.780G>A p.M260I | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- CCNDBP1 | c.715G>C p.E239Q | Missense Mutation (SNP) | VAF 132/377 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- CD164L2 | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 74/142 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- CD180 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CD6 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); called by muse, mutect2
- CDC14C | c.699C>G p.I233M (on ENST00000428251; = p.I126M on NM_152627.3) | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDH23 | c.1501G>A p.D501N | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); called by muse, varscan2
- CDHR1 | c.1123G>C p.E375Q | Missense Mutation (SNP) | VAF 56/253 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CENPE | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CEP112 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 42/90 reads (47%) | called by muse, mutect2, varscan2
- CES5A | c.985C>G p.Q329E | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CETN3 | c.344C>G p.S115* | Nonsense Mutation (SNP) | VAF 22/620 reads (4%) | called by muse, mutect2
- CETN3 | c.342T>A p.D114E | Missense Mutation (SNP) | VAF 22/605 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- CHD3 | c.1004C>G p.S335* | Nonsense Mutation (SNP) | VAF 77/213 reads (36%) | called by muse, mutect2, varscan2
- CHERP | c.221C>A p.P74Q | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CIAO3 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 76/906 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CLHC1 | c.649T>G p.L217V | Missense Mutation (SNP) | VAF 65/241 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLIC5 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 112/369 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- COG3 | c.2412C>A p.F804L | Missense Mutation (SNP) | VAF 31/421 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2
- COG7 | c.1797G>C p.K599N | Missense Mutation (SNP) | VAF 190/1026 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- COL11A1 | c.4855G>T p.D1619Y | Missense Mutation (SNP) | VAF 118/524 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL14A1 | c.2335G>C p.E779Q | Missense Mutation (SNP) | VAF 48/255 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CPA4 | c.1149G>C p.L383F | Missense Mutation (SNP) | VAF 66/335 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPXM2 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CRLF3 | c.28G>T p.E10* | Nonsense Mutation (SNP) | VAF 106/477 reads (22%) | called by muse, mutect2, varscan2
- CRTC2 | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 75/696 reads (11%) | called by muse, mutect2, varscan2
- CRTC3 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 116/597 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- CTNND2 | c.2806G>C p.D936H | Missense Mutation (SNP) | VAF 84/340 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CTSC | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 184/466 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- CUX1 | c.4371G>C p.Q1457H | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.154); called by muse, mutect2
- DCLRE1A | c.2204C>G p.S735C | Missense Mutation (SNP) | VAF 35/308 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- DDC | c.1012C>G p.Q338E | Missense Mutation (SNP) | VAF 60/758 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.139); called by muse, mutect2
- DDR2 | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 66/574 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.413); called by muse, varscan2
- DDX21 | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DHH | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 44/153 reads (29%) | called by muse, mutect2, varscan2
- DMWD | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 78/152 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, varscan2
- DNAH11 | c.411T>G p.I137M | Missense Mutation (SNP) | VAF 60/264 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- DNAH14 | c.6429G>C p.M2143I (on ENST00000445597; = p.M2796I on NM_001367479.1) | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DNAH5 | c.11521C>G p.Q3841E | Missense Mutation (SNP) | VAF 159/892 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DNAH8 | c.2131-1G>C p.X711_splice | Splice Site (SNP) | VAF 71/273 reads (26%) | called by muse, mutect2, varscan2
- DNAH8 | c.4208C>G p.S1403C | Missense Mutation (SNP) | VAF 156/380 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DNAJB11 | c.12G>C p.Q4H | Missense Mutation (SNP) | VAF 50/738 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- DNHD1 | c.8313G>C p.E2771D | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- DOCK1 | c.68G>C p.R23T | Missense Mutation (SNP) | VAF 46/284 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DOLPP1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 69/315 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DONSON | c.1289G>C p.G430A | Missense Mutation (SNP) | VAF 88/375 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DONSON | c.1128G>C p.K376N | Missense Mutation (SNP) | VAF 64/315 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DPH1 | c.626G>C p.G209A | Missense Mutation (SNP) | VAF 81/213 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DPP10 | c.47C>G p.S16* | Nonsense Mutation (SNP) | VAF 33/158 reads (21%) | called by muse, mutect2, varscan2
- DRC7 | c.1723C>G p.L575V | Missense Mutation (SNP) | VAF 92/317 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- DUS3L | c.1003G>C p.E335Q | Missense Mutation (SNP) | VAF 103/491 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUSP10 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 86/769 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- DUSP15 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 36/174 reads (21%) | called by muse, mutect2
- DYNC1LI2 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 54/244 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DYSF | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 108/453 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EEA1 | c.2449G>C p.E817Q | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- EFCAB5 | c.2392C>A p.Q798K | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- EFEMP2 | c.853G>C p.D285H | Missense Mutation (SNP) | VAF 54/249 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- EIF3I | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- EIF4G1 | c.2626G>A p.E876K (on ENST00000346169 / NM_198241.3; = p.E681K on NM_004953.5) | Missense Mutation (SNP) | VAF 114/593 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ELF1 | c.973C>G p.Q325E | Missense Mutation (SNP) | VAF 30/384 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.137); called by muse, mutect2
- ELOA2 | c.945G>C p.K315N | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- EMILIN3 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 55/247 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- EML3 | c.2032G>C p.D678H | Missense Mutation (SNP) | VAF 67/423 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EML6 | c.4252C>G p.L1418V | Missense Mutation (SNP) | VAF 34/458 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.463); called by muse, mutect2
- ENO4 | c.805C>G p.Q269E (on ENST00000622726; = p.Q268E on NM_001242699.2) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- ENTPD2 | c.433C>G p.H145D | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.055); called by muse, varscan2
- ERAP2 | c.2553G>C p.K851N | Missense Mutation (SNP) | VAF 98/361 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- ESR1 | c.812G>A p.R271K | Missense Mutation (SNP) | VAF 69/171 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ETV6 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 20/545 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.165); called by muse, mutect2
- FAF2 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 79/465 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FAT1 | c.5392G>A p.D1798N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAT4 | c.11184G>C p.L3728F | Missense Mutation (SNP) | VAF 51/227 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FBXL16 | c.1081G>T p.D361Y | Missense Mutation (SNP) | VAF 101/472 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FCGR1A | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 46/1179 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.183); called by muse, mutect2
- FCRL1 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 51/378 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FECH | c.1058C>G p.S353C | Missense Mutation (SNP) | VAF 84/216 reads (39%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- FERMT3 | c.723C>G p.I241M | Missense Mutation (SNP) | VAF 105/648 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- FGD3 | c.1650G>C p.K550N | Missense Mutation (SNP) | VAF 67/262 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FLT1 | c.3554C>G p.S1185* | Nonsense Mutation (SNP) | VAF 47/245 reads (19%) | called by muse, mutect2, varscan2
- FOXD4L6 | c.970C>G p.L324V | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); called by mutect2, varscan2
- FRMPD4 | c.1868G>A p.R623K | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- FUT8 | c.1138G>C p.E380Q (on ENST00000360689 / NM_001371534.1; = p.E217Q on NM_004480.4) | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- GALNT13 | c.976-1G>A p.X326_splice | Splice Site (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- GALT | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 166/678 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GARRE1 | c.2756C>A p.S919* | Nonsense Mutation (SNP) | VAF 141/554 reads (25%) | called by muse, mutect2, varscan2
- GASK1B | c.630G>C p.E210D | Missense Mutation (SNP) | VAF 159/393 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- GFY | c.1239C>A p.F413L | Missense Mutation (SNP) | VAF 78/380 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- GNA14 | c.362C>G p.S121C | Missense Mutation (SNP) | VAF 33/251 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GNB5 | c.136G>A p.E46K (on ENST00000261837 / NM_016194.4; = p.E4K on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/466 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPATCH4 | c.440+3G>C | Splice Region (SNP) | VAF 67/398 reads (17%) | called by muse, mutect2, varscan2
- GPR132 | c.921C>G p.I307M | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- GPR158 | c.1670C>T p.S557L | Missense Mutation (SNP) | VAF 75/390 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- GPRASP2 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 77/294 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- GSTO2 | c.495C>G p.F165L | Missense Mutation (SNP) | VAF 51/224 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- GSTZ1 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, varscan2
- GTF2H4 | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 79/363 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GUCY2F | c.2326C>T p.P776S | Missense Mutation (SNP) | VAF 56/269 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- H4C4 | c.303C>A p.F101L | Missense Mutation (SNP) | VAF 20/345 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2
- HADHA | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 100/632 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- HADHA | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 222/1070 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HEATR6 | c.1643C>G p.S548* | Nonsense Mutation (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2, varscan2
- HECW1 | c.2178G>C p.K726N | Missense Mutation (SNP) | VAF 54/247 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- HELQ | c.1669G>C p.D557H | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- HHLA2 | c.912G>C p.L304F | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HIPK3 | c.698C>A p.S233Y | Missense Mutation (SNP) | VAF 47/228 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOGA1 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 31/712 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HPSE2 | c.562C>G p.L188V | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- HSPA4 | c.2017G>C p.D673H | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- IARS2 | c.2663C>G p.S888* | Nonsense Mutation (SNP) | VAF 35/528 reads (7%) | called by muse, mutect2
- IGFN1 | c.2173G>C p.E725Q (on ENST00000295591 / NM_001367841.1; = p.E3182Q on NM_001164586.2) | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- IL1RAPL2 | c.2006G>A p.S669N | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- IMPA1 | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 67/508 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.017); called by muse, varscan2
- INCENP | c.2696C>A p.S899* (on ENST00000394818 / NM_001040694.2; = p.S895* on NM_020238.3) | Nonsense Mutation (SNP) | VAF 49/258 reads (19%) | called by muse, mutect2, varscan2
- ITGA9 | c.1786C>G p.L596V | Missense Mutation (SNP) | VAF 131/713 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- ITGAV | c.2527C>T p.H843Y | Missense Mutation (SNP) | VAF 54/282 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- ITGB1 | c.2279G>A p.R760K | Missense Mutation (SNP) | VAF 72/415 reads (17%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ITGB4 | c.1813C>A p.Q605K | Missense Mutation (SNP) | VAF 99/484 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITPKB | c.1180G>C p.E394Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.079); called by muse, mutect2
- ITPKC | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 183/800 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- IVNS1ABP | c.1177G>T p.D393Y | Missense Mutation (SNP) | VAF 71/686 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- JMY | c.2299G>A p.E767K | Missense Mutation (SNP) | VAF 69/179 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- KANK4 | c.1487C>G p.S496C | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- KCTD2 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 72/325 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- KCTD3 | c.855C>G p.F285L | Missense Mutation (SNP) | VAF 82/613 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- KDM4A | c.3135C>G p.I1045M | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KDM6A | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 117/603 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- KIAA0100 | c.4051C>T p.Q1351* | Nonsense Mutation (SNP) | VAF 58/808 reads (7%) | called by muse, mutect2
- KIAA1109 | c.5578G>A p.E1860K | Missense Mutation (SNP) | VAF 81/200 reads (41%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- KIF15 | c.1204G>C p.E402Q | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- KIF27 | c.1825C>T p.P609S | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KIF7 | c.663C>G p.F221L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KLHL14 | c.894G>C p.M298I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.38); called by muse, varscan2
- LCMT2 | c.217C>T p.Q73* | Nonsense Mutation (SNP) | VAF 62/138 reads (45%) | called by muse, varscan2
- LGSN | c.1055C>G p.S352C | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- LILRA4 | c.980C>A p.S327* | Nonsense Mutation (SNP) | VAF 18/48 reads (38%) | called by muse, mutect2, varscan2
- LMBRD1 | c.1113T>G p.S371R (on ENST00000649011; = p.S349R on NM_018368.4) | Missense Mutation (SNP) | VAF 81/265 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- LRP1B | c.5560G>C p.E1854Q | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- LRRC6 | c.1035C>G p.I345M | Missense Mutation (SNP) | VAF 19/337 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.055); called by muse, mutect2
- LRRTM3 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 123/612 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- LTBP3 | c.42G>C p.E14D | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LTN1 | c.5137G>A p.E1713K | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LZTFL1 | c.657G>C p.K219N | Missense Mutation (SNP) | VAF 51/242 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- MAGED2 | c.20G>T p.S7I | Missense Mutation (SNP) | VAF 38/668 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.054); called by muse, mutect2
- MAP2 | c.1231G>C p.E411Q | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- MCF2 | c.1718G>C p.R573T | Missense Mutation (SNP) | VAF 15/284 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.544); called by muse, mutect2
- MCM3AP | c.3488T>C p.L1163P | Missense Mutation (SNP) | VAF 84/402 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.157); called by muse, varscan2
- MED14 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MED15 | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 226/532 reads (42%) | called by muse, mutect2, varscan2
- MEX3A | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MGAM | c.3634C>G p.L1212V | Missense Mutation (SNP) | VAF 60/307 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- MICALL2 | c.1763G>A p.R588K | Missense Mutation (SNP) | VAF 90/549 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MPDZ | c.826G>C p.A276P | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- MPPE1 | c.618C>G p.I206M | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- MRPS10 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 99/599 reads (17%) | called by muse, mutect2, varscan2
- MSI2 | c.718C>G p.Q240E | Missense Mutation (SNP) | VAF 44/271 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- MTR | c.508G>C p.D170H | Missense Mutation (SNP) | VAF 109/800 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MTX2 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- MUC16 | c.25414G>C p.D8472H | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- MXD1 | c.417G>C p.E139D | Missense Mutation (SNP) | VAF 82/286 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MXRA5 | c.5261C>T p.S1754F | Missense Mutation (SNP) | VAF 47/322 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- MYH14 | c.3148G>A p.E1050K | Missense Mutation (SNP) | VAF 29/354 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- NAPRT | c.850C>T p.Q284* | Nonsense Mutation (SNP) | VAF 59/358 reads (16%) | called by muse, mutect2, varscan2
- NBEA | c.4993C>G p.Q1665E | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NBEA | c.7954G>A p.E2652K | Missense Mutation (SNP) | VAF 17/321 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.791); called by muse, mutect2
- NBEAL2 | c.4081G>A p.E1361K | Missense Mutation (SNP) | VAF 185/710 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- NBPF3 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 56/546 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.433); called by muse, mutect2
- NCKAP5 | c.2553G>C p.E851D | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NCSTN | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 124/829 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLRP11 | c.2246G>C p.R749T | Missense Mutation (SNP) | VAF 49/219 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- NOL6 | c.242C>G p.S81C | Missense Mutation (SNP) | VAF 89/334 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- NSD2 | c.3520G>C p.E1174Q | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- NUDT13 | c.579C>G p.I193M | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- OPA1 | c.2911G>T p.D971Y (on ENST00000361510 / NM_130837.3; = p.D916Y on NM_015560.3) | Missense Mutation (SNP) | VAF 17/519 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- OR10AG1 | c.656T>G p.L219W | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR13C5 | c.716C>G p.S239C | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR2M5 | c.791C>G p.S264C | Missense Mutation (SNP) | VAF 54/500 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- OR2T11 | c.629T>C p.I210T | Missense Mutation (SNP) | VAF 52/418 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR4M1 | c.208G>C p.D70H | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- OR51G2 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.033); called by muse, varscan2
- PAK2 | c.1347G>C p.L449F | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PAK5 | c.1579G>C p.E527Q | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- PALLD | c.333G>C p.K111N | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- PALM3 | c.1054G>A p.E352K (on ENST00000340790; = p.E367K on NM_001145028.2) | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2
- PANK3 | c.825G>A p.M275I | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- PCDH12 | c.198C>A p.F66L | Missense Mutation (SNP) | VAF 67/254 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDHA1 | c.2123C>T p.S708F | Missense Mutation (SNP) | VAF 112/632 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDHGA10 | c.1288G>C p.D430H | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGB1 | c.2027A>T p.E676V | Missense Mutation (SNP) | VAF 109/539 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCNT | c.7714G>C p.E2572Q | Missense Mutation (SNP) | VAF 57/253 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- PCNX3 | c.3380-8C>T | Splice Region (SNP) | VAF 92/472 reads (19%) | called by muse, mutect2, varscan2
- PDLIM7 | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 40/387 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.11); called by muse, mutect2
- PFAS | c.2842G>C p.E948Q | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PFN1 | c.132+8G>C | Splice Region (SNP) | VAF 50/137 reads (36%) | called by muse, mutect2, varscan2
- PGBD1 | c.771G>C p.M257I | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHC3 | c.2818G>A p.E940K (on ENST00000494943 / NM_001308116.2; = p.E952K on NM_024947.4) | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- PHLDB3 | c.82C>A p.H28N | Missense Mutation (SNP) | VAF 66/260 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, varscan2
- PI16 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 137/383 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PI4K2A | c.259C>G p.Q87E | Missense Mutation (SNP) | VAF 80/314 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- PIAS2 | c.1441G>T p.E481* | Nonsense Mutation (SNP) | VAF 28/318 reads (9%) | called by muse, mutect2
- PIP4P1 | c.722G>C p.G241A | Missense Mutation (SNP) | VAF 74/316 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PLEKHA6 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 74/622 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PLEKHA7 | c.370T>G p.S124A | Missense Mutation (SNP) | VAF 87/523 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- PLEKHG3 | c.1603G>A p.E535K (on ENST00000394691; = p.E591K on NM_001308147.2) | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PLEKHG4B | c.2175G>C p.K725N (on ENST00000283426; = p.K1081N on NM_052909.5) | Missense Mutation (SNP) | VAF 95/495 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- PLEKHH1 | c.1535C>G p.S512C | Missense Mutation (SNP) | VAF 114/610 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PLXDC2 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PNPLA2 | c.122C>G p.T41R | Missense Mutation (SNP) | VAF 59/305 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POLQ | c.4033A>G p.K1345E | Missense Mutation (SNP) | VAF 66/237 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POLR1E | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.056); called by muse, mutect2
- POM121L2 | c.2911C>G p.Q971E | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- POMZP3 | c.44G>A p.R15K | Missense Mutation (SNP) | VAF 128/755 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.107G>C p.R36P | Missense Mutation (SNP) | VAF 101/486 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PPFIBP2 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 30/344 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2
- PRB2 | c.1174C>T p.Q392* | Nonsense Mutation (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- PRKAB1 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- PRKAR2A | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 21/495 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.094); called by muse, mutect2
- PRPF3 | c.1341A>C p.K447N | Missense Mutation (SNP) | VAF 84/695 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PRRC2C | c.1726G>T p.E576* (on ENST00000367742; = p.E574* on NM_015172.4) | Nonsense Mutation (SNP) | VAF 18/456 reads (4%) | called by muse, mutect2
- PRSS35 | c.325C>G p.Q109E | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSMA6 | c.555G>C p.K185N | Missense Mutation (SNP) | VAF 55/272 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PSMC4 | c.456G>A p.M152I | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTPRE | c.600G>C p.E200D | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PUM3 | c.1687G>C p.E563Q | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- PVALEF | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.8); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- PXK | c.709C>G p.L237V | Missense Mutation (SNP) | VAF 78/203 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.179); called by muse, varscan2
- QSER1 | c.3718C>T p.Q1240* (on ENST00000399302; = p.Q1369* on NM_001076786.3) | Nonsense Mutation (SNP) | VAF 20/87 reads (23%) | called by muse, mutect2, varscan2
- R3HDM1 | c.209C>G p.S70C | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- R3HDM1 | c.585G>C p.M195I | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- RAB29 | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 78/621 reads (13%) | called by muse, mutect2, varscan2
- RASIP1 | c.997C>T p.Q333* | Nonsense Mutation (SNP) | VAF 113/598 reads (19%) | called by muse, mutect2, varscan2
- RBM12B | c.1372G>C p.E458Q | Missense Mutation (SNP) | VAF 58/539 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM19 | c.1590G>C p.Q530H | Missense Mutation (SNP) | VAF 72/309 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RIMS1 | c.2447C>G p.S816* | Nonsense Mutation (SNP) | VAF 13/117 reads (11%) | called by muse, mutect2
- RIPPLY2 | c.225C>G p.F75L | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- RMDN2 | c.472G>A p.D158N (on ENST00000354545 / NM_001322212.2; = p.D336N on NM_144713.5) | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- RNF111 | c.665C>A p.S222* | Nonsense Mutation (SNP) | VAF 40/88 reads (45%) | called by muse, mutect2, varscan2
- RNF19A | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 101/370 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RNF20 | c.2431C>G p.L811V | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.076); called by muse, mutect2
- RNF213 | c.10423+7C>T | Splice Region (SNP) | VAF 49/194 reads (25%) | called by muse, mutect2, varscan2
- RNF40 | c.1687G>C p.E563Q | Missense Mutation (SNP) | VAF 72/398 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- RNF6 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 93/422 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RP1 | c.3179G>C p.R1060T | Missense Mutation (SNP) | VAF 63/274 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RRAGB | c.542C>T p.A181V (on ENST00000262850 / NM_016656.4; = p.A153V on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/255 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- RREB1 | c.4272G>C p.K1424N | Missense Mutation (SNP) | VAF 66/368 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RRN3 | c.520G>T p.D174Y | Missense Mutation (SNP) | VAF 50/434 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RSPO2 | c.621G>C p.K207N | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- RYR3 | c.1360G>C p.E454Q | Missense Mutation (SNP) | VAF 45/65 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- SCNN1G | c.365G>C p.R122T | Missense Mutation (SNP) | VAF 92/395 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- SEC14L1 | c.2042+6G>A | Splice Region (SNP) | VAF 61/78 reads (78%) | called by muse, mutect2, varscan2
- SERPINE3 | c.313C>G p.Q105E | Missense Mutation (SNP) | VAF 138/499 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SETD9 | c.60C>A p.F20L | Missense Mutation (SNP) | VAF 98/515 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SHANK1 | c.3305C>T p.S1102L | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIAE | c.604C>T p.H202Y | Missense Mutation (SNP) | VAF 87/188 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC10A3 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- SLC16A2 | c.1100C>G p.S367* | Nonsense Mutation (SNP) | VAF 61/450 reads (14%) | called by muse, mutect2, varscan2
- SLC18A1 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC1A3 | c.909G>C p.E303D | Missense Mutation (SNP) | VAF 95/350 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- SLC24A1 | c.2102G>A p.R701K | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC35E1 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 186/739 reads (25%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC35E1 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 85/301 reads (28%) | called by muse, mutect2, varscan2
- SLC4A8 | c.3100G>C p.E1034Q | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLMAP | c.1564G>A p.D522N (on ENST00000428312 / NM_001377924.1; = p.D584N on NM_007159.5) | Missense Mutation (SNP) | VAF 162/679 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMAD1 | c.807del p.K269Nfs*112 | Frame Shift Del (DEL) | VAF 101/257 reads (39%) | called by mutect2, pindel, varscan2
- SMARCC1 | c.1072C>G p.Q358E | Missense Mutation (SNP) | VAF 124/430 reads (29%) | SIFT tolerated (0.77); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- SNRNP27 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 68/342 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- SNX25 | c.1627G>C p.E543Q | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- SNX30 | c.391C>T p.R131* | Nonsense Mutation (SNP) | VAF 56/272 reads (21%) | called by muse, varscan2
- SOWAHD | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2
- SOX12 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- SOX5 | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SPACA3 | c.602G>A p.C201Y | Missense Mutation (SNP) | VAF 63/334 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPAG5 | c.2001G>C p.E667D | Missense Mutation (SNP) | VAF 79/428 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- SPAG5 | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 52/286 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- SPARCL1 | c.1832C>G p.S611C | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPDEF | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 19/518 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.129); called by muse, mutect2
- SPIRE1 | c.2178G>T p.R726S (on ENST00000409402 / NM_001128626.2; = p.R712S on NM_020148.3) | Missense Mutation (SNP) | VAF 295/343 reads (86%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPRED2 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 92/312 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPTA1 | c.6430G>C p.E2144Q | Missense Mutation (SNP) | VAF 120/809 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- STAMBP | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- STRN | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 94/300 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STYXL2 | c.1528G>C p.E510Q | Missense Mutation (SNP) | VAF 26/387 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); called by muse, mutect2
- TARBP1 | c.4469C>T p.S1490L | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- TAS2R39 | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 12/344 reads (3%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2
- TASOR2 | c.1672C>A p.H558N | Missense Mutation (SNP) | VAF 42/584 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2
- TBCCD1 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 84/454 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TBX15 | c.1750G>A p.G584S (on ENST00000369429 / NM_001330677.2; = p.G478S on NM_152380.3) | Missense Mutation (SNP) | VAF 110/222 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TECPR1 | c.456G>C p.K152N | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TESPA1 | c.578A>C p.K193T (on ENST00000316577 / NM_001098815.3; = p.K55T on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/295 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- THUMPD2 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM174 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 60/272 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- TMEM38A | c.873G>C p.R291S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TMEM79 | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 29/97 reads (30%) | called by muse, mutect2, varscan2
- TMPO | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 83/350 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- TPX2 | c.1351G>C p.E451Q | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- TRAPPC9 | c.3395C>G p.S1132C | Missense Mutation (SNP) | VAF 84/443 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- TSGA13 | c.28C>G p.Q10E | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTC6 | c.1562G>C p.*521Sext*8 (on ENST00000267368; = p.*1887Sext*8 on NM_001310135.3) | Nonstop Mutation (SNP) | VAF 29/128 reads (23%) | called by muse, mutect2, varscan2
- TTN | c.23851G>A p.E7951K (on ENST00000591111; = p.E7024K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTPAL | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 150/845 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- U2AF1L4 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 74/283 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- UBE4B | c.2194G>C p.E732Q (on ENST00000343090 / NM_001105562.3; = p.E603Q on NM_006048.5) | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT tolerated (0.95); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- UBQLN2 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- UBTF | c.2230G>C p.E744Q | Missense Mutation (SNP) | VAF 75/171 reads (44%) | PolyPhen benign (0.037); called by muse, mutect2, varscan2
- UBTF | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 117/293 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- UBXN11 | c.812C>T p.S271L (on ENST00000374221 / NM_183008.2; = p.S238L on NM_145345.2) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- UNC13A | c.40G>C p.D14H | Missense Mutation (SNP) | VAF 67/295 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- USH1C | c.471G>C p.K157N | Missense Mutation (SNP) | VAF 102/400 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP29 | c.2629G>C p.G877R | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VAMP7 | c.471G>C p.L157F | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS33A | c.507G>C p.Q169H | Missense Mutation (SNP) | VAF 25/368 reads (7%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.713); called by muse, mutect2
- VPS45 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 57/407 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, varscan2
- WDHD1 | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 60/266 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- WDHD1 | c.1861C>T p.L621F | Missense Mutation (SNP) | VAF 58/224 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- WDPCP | c.2176G>A p.D726N | Missense Mutation (SNP) | VAF 15/293 reads (5%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.994); called by muse, mutect2
- WDR97 | c.2440C>G p.L814V | Missense Mutation (SNP) | VAF 96/634 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.026); called by muse, varscan2
- WT1 | c.214C>G p.Q72E | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBBX | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- ZBTB3 | c.156C>G p.F52L | Missense Mutation (SNP) | VAF 34/307 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ZKSCAN1 | c.540C>G p.F180L | Missense Mutation (SNP) | VAF 114/748 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZKSCAN1 | c.1297C>T p.H433Y | Missense Mutation (SNP) | VAF 91/397 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ZNF189 | c.1049G>A p.G350E | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ZNF221 | c.1799C>G p.S600* | Nonsense Mutation (SNP) | VAF 9/85 reads (11%) | called by muse, mutect2
- ZNF233 | c.1919G>C p.R640T | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- ZNF26 | c.719C>G p.S240C | Missense Mutation (SNP) | VAF 53/234 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- ZNF646 | c.380G>A p.W127* | Nonsense Mutation (SNP) | VAF 35/143 reads (24%) | called by muse, mutect2, varscan2
- ZNF813 | c.1344C>G p.F448L | Missense Mutation (SNP) | VAF 73/324 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- ZNF879 | c.1523G>C p.G508A | Missense Mutation (SNP) | VAF 58/215 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZSCAN26 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- ABCA13 | c.6859C>T p.L2287= | Silent (SNP) | VAF 24/110 reads (22%) | called by muse, varscan2
- ADGRD2 | c.2898G>A p.R966= | Silent (SNP) | VAF 34/131 reads (26%) | called by muse, mutect2, varscan2
- ADGRG6 | c.378G>A p.E126= | Silent (SNP) | VAF 21/97 reads (22%) | called by muse, mutect2, varscan2
- AGL | c.4539C>T p.F1513= | Silent (SNP) | VAF 88/418 reads (21%) | catalogued as rs752519483; ClinVar: likely benign; called by muse, mutect2, varscan2
- AGO2 | c.630C>G p.L210= | Silent (SNP) | VAF 72/314 reads (23%) | called by muse, mutect2, varscan2
- ALG13 | c.1830C>T p.L610= | Silent (SNP) | VAF 87/406 reads (21%) | catalogued as COSV52638369; called by muse, mutect2, varscan2
- ALOX15B | c.1524C>G p.L508= | Silent (SNP) | VAF 25/201 reads (12%) | called by muse, mutect2, varscan2
- ANKMY1 | c.309C>T p.I103= | Silent (SNP) | VAF 66/322 reads (20%) | catalogued as COSV56041498; called by muse, mutect2, varscan2
- AP3S1 | c.93C>T p.I31= | Silent (SNP) | VAF 18/166 reads (11%) | called by muse, varscan2
- APOBR | c.45G>A p.L15= | Silent (SNP) | VAF 11/203 reads (5%) | called by muse, mutect2
- APOC1 | c.9C>A p.L3= | Silent (SNP) | VAF 22/423 reads (5%) | called by muse, mutect2
- ARHGAP31 | c.1782G>A p.L594= | Silent (SNP) | VAF 55/393 reads (14%) | called by muse, mutect2, varscan2
- ARHGAP5 | c.474A>G p.G158= | Silent (SNP) | VAF 109/216 reads (50%) | called by muse, mutect2, varscan2
- ATAD2 | c.4077C>A p.I1359= | Silent (SNP) | VAF 42/394 reads (11%) | called by muse, mutect2, varscan2
- ATAD2B | c.162C>T p.P54= | Silent (SNP) | VAF 39/248 reads (16%) | called by muse, mutect2, varscan2
- ATP8B3 | c.1656C>T p.L552= | Silent (SNP) | VAF 76/300 reads (25%) | catalogued as rs375560334; called by muse, mutect2, varscan2
- B3GALT5 | c.282C>T p.F94= | Silent (SNP) | VAF 34/206 reads (17%) | called by muse, mutect2
- BORCS6 | c.444G>A p.E148= | Silent (SNP) | VAF 21/485 reads (4%) | called by muse, mutect2
- CABIN1 | c.5055G>A p.R1685= | Silent (SNP) | VAF 74/180 reads (41%) | catalogued as COSV54080578; called by muse, mutect2, varscan2
- CBLIF | c.684C>G p.L228= | Silent (SNP) | VAF 80/472 reads (17%) | called by muse, mutect2, varscan2
- CCDC154 | c.321G>A p.V107= | Silent (SNP) | VAF 21/139 reads (15%) | catalogued as rs1001455620; called by muse, mutect2, varscan2
- CD53 | c.352C>T p.L118= | Silent (SNP) | VAF 12/264 reads (5%) | called by muse, mutect2
- CD82 | c.803G>A p.*268= | Silent (SNP) | VAF 26/283 reads (9%) | called by muse, mutect2
- CDKAL1 | c.1047G>A p.L349= | Silent (SNP) | VAF 58/217 reads (27%) | called by muse, mutect2, varscan2
- CERK | c.1431G>A p.K477= | Silent (SNP) | VAF 155/504 reads (31%) | called by mutect2, varscan2
- CHSY1 | c.30C>A p.L10= | Silent (SNP) | VAF 71/262 reads (27%) | called by muse, mutect2, varscan2
- COL6A1 | c.2046G>A p.R682= | Silent (SNP) | VAF 93/446 reads (21%) | catalogued as COSV62615752; called by muse, mutect2, varscan2
- COL8A1 | c.1635G>T p.G545= | Silent (SNP) | VAF 11/63 reads (17%) | called by muse, mutect2, varscan2
- CRTC2 | c.537G>A p.V179= | Silent (SNP) | VAF 67/498 reads (13%) | called by muse, mutect2, varscan2
- CSPG5 | c.222G>A p.S74= | Silent (SNP) | VAF 24/115 reads (21%) | called by muse, mutect2, varscan2
- CST4 | c.30C>T p.L10= | Silent (SNP) | VAF 42/195 reads (22%) | catalogued as rs560056822; called by muse, mutect2, varscan2
- CSTF2 | c.1581G>A p.Q527= | Silent (SNP) | VAF 31/143 reads (22%) | called by muse, mutect2, varscan2
- CUX1 | c.1317G>C p.L439= (on ENST00000437600 / NM_181500.4; = p.L441= on NM_001913.5) | Silent (SNP) | VAF 50/308 reads (16%) | catalogued as rs782281689; called by muse, mutect2, varscan2
- DDR2 | c.558C>G p.V186= | Silent (SNP) | VAF 66/706 reads (9%) | catalogued as COSV100906936; called by muse, mutect2
- DDX39B | c.834C>T p.L278= | Silent (SNP) | VAF 87/513 reads (17%) | catalogued as COSV100795264; called by muse, mutect2, varscan2
- DENND4B | c.1413C>T p.F471= | Silent (SNP) | VAF 45/781 reads (6%) | catalogued as COSV100768367, COSV63410395; called by muse, mutect2
- DLEC1 | c.2448C>A p.V816= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs758661030, COSV57301239; called by muse, mutect2, varscan2
- DOCK2 | c.2580C>G p.V860= | Silent (SNP) | VAF 61/369 reads (17%) | called by muse, mutect2, varscan2
- DPYSL5 | c.84C>T p.V28= | Silent (SNP) | VAF 131/460 reads (28%) | catalogued as COSV99981545; called by muse, mutect2, varscan2
- DSCAML1 | c.327C>T p.A109= (on ENST00000321322; = p.A49= on NM_020693.4) | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs1237768281, COSV100355342; called by muse, mutect2, varscan2
- DZIP3 | c.2211C>G p.G737= | Silent (SNP) | VAF 82/137 reads (60%) | called by muse, mutect2, varscan2
- EDEM3 | c.1602C>G p.L534= | Silent (SNP) | VAF 45/342 reads (13%) | called by muse, mutect2, varscan2
- ERC1 | c.2704C>T p.L902= (on ENST00000360905 / NM_178040.4; = p.L874= on NM_178039.4) | Silent (SNP) | VAF 73/307 reads (24%) | called by muse, mutect2, varscan2
- ERCC6 | c.1974C>T p.V658= | Silent (SNP) | VAF 73/416 reads (18%) | catalogued as rs1463979210; called by muse, mutect2, varscan2
- ERVMER34-1 | c.1398G>A p.E466= | Silent (SNP) | VAF 53/154 reads (34%) | called by muse, mutect2, varscan2
- FAM151B | c.147G>C p.L49= | Silent (SNP) | VAF 37/218 reads (17%) | catalogued as COSV56472954; called by muse, mutect2, varscan2
- FAM20A | c.1191C>T p.I397= | Silent (SNP) | VAF 165/369 reads (45%) | catalogued as rs748206961, COSV99873208; called by muse, mutect2, varscan2
- FAM47B | c.1389C>T p.L463= | Silent (SNP) | VAF 52/205 reads (25%) | called by muse, mutect2, varscan2
- FBXO24 | c.747C>T p.I249= (on ENST00000241071 / NM_033506.3; = p.I287= on NM_012172.5) | Silent (SNP) | VAF 99/406 reads (24%) | catalogued as rs572704133, COSV53825775; called by muse, mutect2, varscan2
- FHOD3 | c.1494G>C p.L498= (on ENST00000359247 / NM_001281739.3; = p.L515= on NM_025135.5) | Silent (SNP) | VAF 30/944 reads (3%) | called by muse, mutect2
- FLNC | c.2271C>T p.N757= | Silent (SNP) | VAF 54/115 reads (47%) | catalogued as rs779105468; called by muse, mutect2, varscan2
- FOXA1 | c.1206C>A p.I402= | Silent (SNP) | VAF 226/1763 reads (13%) | catalogued as COSV99032067; called by muse, mutect2, varscan2
- FZD10 | c.1653C>T p.I551= | Silent (SNP) | VAF 29/115 reads (25%) | called by muse, mutect2, varscan2
- GBP2 | c.213G>A p.V71= | Silent (SNP) | VAF 40/209 reads (19%) | called by muse, mutect2, varscan2
- GET1 | c.51C>T p.F17= | Silent (SNP) | VAF 113/503 reads (22%) | called by muse, varscan2
- GFI1B | c.992G>A p.*331= | Silent (SNP) | VAF 28/288 reads (10%) | called by muse, mutect2
- GRIK2 | c.1975C>T p.L659= | Silent (SNP) | VAF 77/404 reads (19%) | called by muse, mutect2, varscan2
- GRIN2C | c.886C>T p.L296= | Silent (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2
- HGSNAT | c.1092C>G p.L364= | Silent (SNP) | VAF 55/220 reads (25%) | catalogued as COSV52819055; called by muse, mutect2, varscan2
- HMCN1 | c.11142C>T p.N3714= | Silent (SNP) | VAF 45/404 reads (11%) | called by muse, mutect2, varscan2
- HMGCR | c.1140G>A p.Q380= | Silent (SNP) | VAF 73/324 reads (23%) | called by muse, mutect2, varscan2
- INSRR | c.3204G>A p.K1068= | Silent (SNP) | VAF 58/356 reads (16%) | catalogued as COSV63873955; called by muse, mutect2, varscan2
- INTS1 | c.3351G>C p.L1117= | Silent (SNP) | VAF 15/369 reads (4%) | called by muse, mutect2
- IRX4 | c.831G>A p.P277= | Silent (SNP) | VAF 60/280 reads (21%) | catalogued as rs1424231959; called by muse, mutect2, varscan2
- KBTBD4 | c.178C>A p.R60= | Silent (SNP) | VAF 140/642 reads (22%) | called by muse, mutect2, varscan2
- KCNC4 | c.1776C>T p.L592= | Silent (SNP) | VAF 23/556 reads (4%) | catalogued as rs1206631242; called by muse, mutect2
- KCNG2 | c.837C>T p.L279= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs759782870; called by muse, mutect2, varscan2
- KCNH4 | c.88C>T p.L30= | Silent (SNP) | VAF 19/36 reads (53%) | called by muse, varscan2
- KCTD15 | c.570C>T p.I190= | Silent (SNP) | VAF 79/315 reads (25%) | catalogued as rs1350439886; called by muse, mutect2, varscan2
- KCTD3 | c.985C>T p.L329= | Silent (SNP) | VAF 34/215 reads (16%) | called by muse, mutect2, varscan2
- KLC3 | c.957G>A p.E319= | Silent (SNP) | VAF 84/357 reads (24%) | catalogued as rs1422034217; called by muse, mutect2, varscan2
- LCE1F | c.138C>T p.V46= | Silent (SNP) | VAF 151/1138 reads (13%) | called by muse, mutect2, varscan2
- LRRK2 | c.1876C>T p.L626= | Silent (SNP) | VAF 23/235 reads (10%) | catalogued as rs866253403; called by muse, mutect2, varscan2
- LTBP3 | c.2949C>A p.I983= | Silent (SNP) | VAF 137/750 reads (18%) | called by muse, mutect2, varscan2
- MAFA | c.165C>G p.L55= | Silent (SNP) | VAF 72/501 reads (14%) | catalogued as rs1321405635, COSV61087814; called by muse, mutect2, varscan2
- MAPK14 | c.579C>T p.I193= | Silent (SNP) | VAF 84/589 reads (14%) | called by muse, mutect2, varscan2
- MAST1 | c.528G>A p.V176= | Silent (SNP) | VAF 57/218 reads (26%) | called by muse, mutect2, varscan2
- MCM3AP | c.4998C>T p.L1666= | Silent (SNP) | VAF 24/142 reads (17%) | catalogued as rs780248956; called by muse, mutect2, varscan2
- MDN1 | c.3198G>C p.L1066= | Silent (SNP) | VAF 50/126 reads (40%) | called by muse, mutect2, varscan2
- MED30 | c.162C>G p.L54= | Silent (SNP) | VAF 28/164 reads (17%) | called by muse, mutect2, varscan2
- MIA2 | c.2157C>T p.F719= | Silent (SNP) | VAF 98/633 reads (15%) | catalogued as rs1416933824; called by muse, mutect2, varscan2
- MISP3 | c.441C>T p.I147= (on ENST00000269720; = p.I5= on NM_001291291.2) | Silent (SNP) | VAF 233/907 reads (26%) | called by muse, mutect2, varscan2
- MMP3 | c.414G>A p.L138= | Silent (SNP) | VAF 14/196 reads (7%) | called by muse, mutect2
- MPDZ | c.3189C>T p.I1063= | Silent (SNP) | VAF 42/540 reads (8%) | catalogued as rs758403987; called by muse, mutect2
- MYH14 | c.3219G>A p.L1073= | Silent (SNP) | VAF 64/796 reads (8%) | catalogued as rs1446685939; called by muse, mutect2
- MYO10 | c.687C>T p.I229= | Silent (SNP) | VAF 82/427 reads (19%) | called by muse, mutect2, varscan2
- MYO7A | c.4650G>A p.P1550= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as rs751242817; ClinVar: likely benign; called by muse, mutect2
- NAIF1 | c.378C>T p.T126= | Silent (SNP) | VAF 38/180 reads (21%) | catalogued as rs368942753; called by muse, mutect2, varscan2
- NBPF3 | c.1233G>A p.E411= | Silent (SNP) | VAF 54/536 reads (10%) | called by muse, mutect2
- NCDN | c.804C>T p.I268= | Silent (SNP) | VAF 52/100 reads (52%) | called by muse, mutect2, varscan2
- NCL | c.237G>A p.K79= | Silent (SNP) | VAF 144/625 reads (23%) | catalogued as rs754577866; called by muse, mutect2, varscan2
- NCOA6 | c.1818C>T p.L606= | Silent (SNP) | VAF 64/303 reads (21%) | called by muse, mutect2, varscan2
- NOMO1 | c.2601C>A p.I867= | Silent (SNP) | VAF 172/1423 reads (12%) | called by muse, varscan2
- NUBP1 | c.762C>A p.L254= | Silent (SNP) | VAF 53/239 reads (22%) | called by muse, mutect2, varscan2
- NUDT8 | c.696G>C p.L232= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100039788; called by muse, mutect2
- OBI1 | c.177C>T p.I59= | Silent (SNP) | VAF 70/436 reads (16%) | catalogued as rs1162792961; called by muse, varscan2
- OPLAH | c.3537C>T p.G1179= | Silent (SNP) | VAF 34/468 reads (7%) | called by muse, mutect2
- OR1S2 | c.429G>A p.L143= | Silent (SNP) | VAF 18/112 reads (16%) | catalogued as COSV56920866; called by muse, varscan2
- OR4K13 | c.534C>T p.F178= | Silent (SNP) | VAF 47/188 reads (25%) | catalogued as rs1475338800, COSV59859540; called by muse, mutect2, varscan2
- P2RX5 | c.90C>T p.G30= | Silent (SNP) | VAF 151/321 reads (47%) | called by muse, mutect2, varscan2
- PCDHB8 | c.546C>T p.L182= | Silent (SNP) | VAF 51/430 reads (12%) | catalogued as rs782167553, COSV99175669; called by muse, mutect2, varscan2
- PCSK4 | c.1524C>A p.I508= | Silent (SNP) | VAF 48/161 reads (30%) | called by muse, mutect2, varscan2
- PKD1L3 | c.3276C>T p.L1092= | Silent (SNP) | VAF 33/99 reads (33%) | called by muse, mutect2, varscan2
- PKD2L1 | c.2052G>A p.V684= | Silent (SNP) | VAF 26/222 reads (12%) | called by muse, mutect2, varscan2
- PKDREJ | c.3075C>T p.V1025= | Silent (SNP) | VAF 48/137 reads (35%) | catalogued as rs753064790; called by muse, mutect2, varscan2
- PLAAT5 | c.720C>T p.L240= | Silent (SNP) | VAF 14/132 reads (11%) | catalogued as COSV100080631; called by muse, mutect2, varscan2
- PLEKHO1 | c.117G>A p.E39= | Silent (SNP) | VAF 28/826 reads (3%) | called by muse, mutect2
- PLXNA4 | c.3360C>T p.F1120= | Silent (SNP) | VAF 31/950 reads (3%) | called by muse, mutect2
- PNOC | c.159C>T p.F53= | Silent (SNP) | VAF 15/70 reads (21%) | called by muse, varscan2
- POLDIP3 | c.774G>C p.V258= | Silent (SNP) | VAF 6/148 reads (4%) | called by muse, mutect2
- POLR2A | c.5868C>A p.L1956= | Silent (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
184 further variants in this file (0 protein-altering or splice-affecting, 72 silent, 112 other) are not listed here.
